Somatic mutation profile of tumor specimen TCGA-GC-A3OO-01A (aliquot TCGA-GC-A3OO-01A-11D-A22Z-08) from TCGA case TCGA-GC-A3OO, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 79.6 years (29,065 days).
Specimen TCGA-GC-A3OO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57a55892-4662-4f7a-a8b1-6f20a71c7576.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GC-A3OO-10C (Blood Derived Normal), aliquot TCGA-GC-A3OO-10C-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98fcf3fe-157e-436a-a6e3-9b4439e5f632

The open-access MAF lists 144 somatic variants for this specimen: 100 protein-altering or splice-affecting, 41 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 41, Nonsense Mutation 6, Splice Region 3, 5'UTR 2, Splice Site 1, 3'UTR 1, Frame Shift Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2584A>G p.T862A | Missense Mutation (SNP) | VAF 16/92 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV54062276; called by muse, mutect2, varscan2
- TP53 | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 18/61 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876658468, COSV52675896, COSV52688299, COSV52757395; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB10 | c.1756G>C p.E586Q | Missense Mutation (SNP) | VAF 5/139 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as COSV60622929; called by muse, mutect2
- AKR1C3 | c.248C>T p.S83L | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.35); catalogued as rs1554785174, COSV65910943; called by muse, mutect2
- ANKRD12 | c.3422C>G p.S1141* | Nonsense Mutation (SNP) | VAF 10/108 reads (9%) | catalogued as COSV100041816; called by muse, mutect2
- AQP1 | c.553G>T p.D185Y | Missense Mutation (SNP) | VAF 22/366 reads (6%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.999); catalogued as COSV61267728; called by muse, mutect2
- ARHGEF19 | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV54617917; called by muse, mutect2, varscan2
- ATG2A | c.3834C>G p.I1278M | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV65966978; called by muse, mutect2
- BOLA1 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.77); PolyPhen benign (0.079); catalogued as COSV64967392; called by muse, mutect2
- BTNL3 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.994); catalogued as rs1327415483, COSV100732228, COSV61565700; called by muse, mutect2
- C19orf57 | c.1439C>T p.S480F | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.061); catalogued as COSV60969627; called by muse, mutect2
- CACHD1 | c.3448G>A p.E1150K | Missense Mutation (SNP) | VAF 7/156 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV51551938; called by muse, mutect2
- CCT8 | c.553C>T p.Q185* | Nonsense Mutation (SNP) | VAF 6/72 reads (8%) | catalogued as COSV54505858, COSV99726080; called by muse, mutect2
- CDK2 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.977); catalogued as COSV57187154; called by muse, mutect2, varscan2
- CLGN | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100346751; called by muse, mutect2
- CMPK1 | c.565C>T p.Q189* | Nonsense Mutation (SNP) | VAF 11/194 reads (6%) | catalogued as COSV100898556; called by muse, mutect2
- CNOT4 | c.226C>G p.Q76E | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV59656826; called by muse, mutect2
- COL11A1 | c.3397G>A p.E1133K | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.112); catalogued as COSV62191307; called by muse, mutect2, varscan2
- COL5A1 | c.2034C>T p.P678= | Splice Region (SNP) | VAF 8/92 reads (9%) | catalogued as rs373100663; called by muse, mutect2
- CUX2 | c.3826G>C p.E1276Q | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.03); catalogued as COSV55642403; called by muse, mutect2, varscan2
- DDX5 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.733); catalogued as COSV56750536; called by muse, mutect2, varscan2
- DESI1 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as COSV99611006; called by muse, mutect2
- EDN2 | c.444-1G>A p.X148_splice | Splice Site (SNP) | VAF 5/63 reads (8%) | catalogued as rs1404218686, COSV101006340, COSV65423538; called by muse, mutect2
- EIF4E2 | c.129G>C p.K43N | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs1229847307; called by muse, mutect2
- EMSY | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 34/223 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV58264207; called by muse, mutect2, varscan2
- FDXACB1 | c.782G>T p.R261M | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as COSV52790008; called by muse, mutect2, varscan2
- FKBP14 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1369464099, COSV51653787; called by muse, mutect2
- GBX2 | c.762C>A p.F254L | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60445678; called by muse, mutect2, varscan2
- GUCY1A2 | c.2128C>G p.L710V | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.02); catalogued as COSV56496094; called by muse, mutect2
- HMX2 | c.662C>T p.S221L | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1219110588, COSV100378823; called by muse, mutect2
- IQCH | c.3052G>A p.D1018N | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.215); catalogued as COSV60057642; called by muse, mutect2, varscan2
- ISLR2 | c.121G>C p.E41Q | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.587); catalogued as COSV62303066; called by muse, mutect2, varscan2
- LRRC7 | c.3535G>A p.D1179N (on ENST00000651989 / NM_001370785.2; = p.D1146N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.263); catalogued as COSV50412151, COSV50457035; called by muse, mutect2, varscan2
- LSS | c.1971G>A p.M657I | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.73); PolyPhen benign (0.062); catalogued as COSV62702095; called by muse, mutect2, varscan2
- MAP4K4 | c.3025G>A p.E1009K (on ENST00000347699 / NM_001242559.2; = p.E927K on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.345); catalogued as COSV100155532; called by muse, mutect2
- MRGPRX2 | c.592C>T p.L198F | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV61674697; called by muse, mutect2, varscan2
- MRPS27 | c.1108G>C p.E370Q | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.156); catalogued as COSV54652781; called by muse, mutect2
- NEURL4 | c.2909C>T p.S970F | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV59747742; called by muse, varscan2
- NINL | c.1412C>T p.A471V | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs767619759, COSV54006826; called by muse, mutect2, varscan2
- NOTCH4 | c.5849C>T p.P1950L | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.755); catalogued as COSV66682832; called by muse, mutect2, varscan2
- OR10K1 | c.496C>G p.L166V | Missense Mutation (SNP) | VAF 69/262 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.913); catalogued as COSV56871088, COSV56873325; called by muse, mutect2, varscan2
- OR4X2 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 17/314 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as COSV56584551; called by muse, mutect2
- PCLO | c.5032G>A p.D1678N | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV100435519; called by muse, mutect2
- PDZD2 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 13/332 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV56867698; called by muse, mutect2
- PDZD2 | c.7450G>A p.E2484K | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs1448791109, COSV56867707; called by muse, mutect2
- PHACTR1 | c.1404G>C p.Q468H | Missense Mutation (SNP) | VAF 24/350 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60676379; called by muse, mutect2
- PHLDB2 | c.1270G>A p.D424N | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV67314637; called by muse, mutect2
- PIH1D1 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.187); catalogued as COSV51808175; called by muse, mutect2
- POP1 | c.1235C>G p.S412C | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs757794868, COSV62893800; called by muse, mutect2, varscan2
- PPP4R3A | c.1584G>C p.K528N (on ENST00000554943 / NM_001366432.1; = p.K515N on NM_001284280.1) | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61505921; called by muse, varscan2
- PPP4R3A | c.1504G>A p.D502N (on ENST00000554943 / NM_001366432.1; = p.D489N on NM_001284280.1) | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61505930; called by muse, varscan2
- PRDM9 | c.1337G>A p.S446N | Missense Mutation (SNP) | VAF 71/141 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV57004140; called by muse, mutect2, varscan2
- PTPN13 | c.2870C>G p.A957G | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.05); catalogued as COSV57413691; called by muse, mutect2, varscan2
- PZP | c.2803G>C p.E935Q | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.391); catalogued as COSV54358383, COSV99738156; called by muse, mutect2, varscan2
- RBBP5 | c.871C>T p.H291Y | Missense Mutation (SNP) | VAF 50/256 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); catalogued as COSV52706084; called by muse, mutect2, varscan2
- RECQL | c.1553C>T p.S518F | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV53711115; called by muse, mutect2
- RNF135 | c.901C>G p.Q301E | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60434281; called by muse, mutect2
- RTN4IP1 | c.529C>G p.Q177E | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64806035; called by muse, mutect2, varscan2
- SDR42E1 | c.169G>C p.D57H | Missense Mutation (SNP) | VAF 15/178 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV61094823; called by muse, mutect2
- SEMA4A | c.1580C>G p.S527C | Missense Mutation (SNP) | VAF 75/279 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.895); catalogued as COSV61773550; called by muse, mutect2, varscan2
- SIGLEC1 | c.2563G>A p.E855K | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as COSV52469390; called by muse, mutect2
- SLC25A31 | c.194G>T p.G65V | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55420666; called by muse, mutect2, varscan2
- SPATA31D1 | c.998C>T p.S333F | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); catalogued as COSV61199251; called by muse, mutect2
- SPATS2 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV58921811; called by muse, mutect2
- SPESP1 | c.363C>G p.F121L | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52988713; called by muse, mutect2, varscan2
- SPHKAP | c.2910G>A p.M970I | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV60873571; called by muse, mutect2, varscan2
- SPINK5 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.642); catalogued as COSV56259771; called by muse, mutect2
- SRCAP | c.2912G>T p.R971L | Missense Mutation (SNP) | VAF 45/273 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV52678210; called by muse, mutect2, varscan2
- SRGN | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.028); catalogued as COSV54345299; called by muse, mutect2
- SRPRB | c.40G>A p.G14S | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs951540380, COSV72048441; called by muse, mutect2, varscan2
- ST3GAL1 | c.596G>A p.G199E | Missense Mutation (SNP) | VAF 16/180 reads (9%) | PolyPhen benign (0.102); catalogued as rs1052217664, COSV60615452; called by muse, mutect2
- TANGO6 | c.879G>A p.M293I | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV55770236; called by muse, mutect2
- TDRD6 | c.1501G>C p.E501Q | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV60173932, COSV60177173; called by muse, mutect2, varscan2
- TLN1 | c.2533G>A p.E845K | Missense Mutation (SNP) | VAF 9/157 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as COSV59210288; called by muse, mutect2
- TNFAIP1 | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); catalogued as COSV50228740; called by muse, mutect2, varscan2
- TRIP6 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs546644102, COSV52342651; called by muse, mutect2, varscan2
- TRPM3 | c.1819G>A p.D607N (on ENST00000357533 / NM_001366142.2; = p.D450N on NM_020952.6) | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.601); catalogued as COSV62587563; called by muse, mutect2
- TTC16 | c.40G>A p.G14S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV58853995; called by muse, mutect2, varscan2
- TTC26 | c.224G>A p.R75K | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT tolerated (1); PolyPhen probably damaging (0.982); catalogued as COSV58273491; called by muse, mutect2
- TUBB6 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.551); catalogued as rs1303292713, COSV58353956; called by muse, mutect2, varscan2
- UBAP2 | c.139G>C p.D47H | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62545122, COSV62548234; called by muse, mutect2, varscan2
- UNC13A | c.3203C>T p.P1068L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as COSV53205102; called by muse, mutect2, varscan2
- UST | c.368G>A p.R123K | Missense Mutation (SNP) | VAF 9/180 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.246); catalogued as COSV66549221; called by muse, mutect2
- WFIKKN2 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV60959397, COSV60959767; called by muse, mutect2, varscan2
- YTHDF2 | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV65723868, COSV65724014; called by muse, mutect2
- ZBED1 | c.1304A>G p.N435S | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs748700879, COSV58137250; called by mutect2, varscan2
- ZNF235 | c.706C>G p.H236D | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV52157789, COSV52158021; called by muse, mutect2
- ZNF334 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 9/89 reads (10%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as COSV61619664; called by muse, mutect2
- ZZEF1 | c.5647C>T p.R1883W | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs779287716, COSV67559305; called by muse, mutect2, varscan2
- ADAM29 | c.2326C>T p.Q776* | Nonsense Mutation (SNP) | VAF 14/136 reads (10%) | called by muse, mutect2, varscan2
- AKR1B15 | c.737G>A p.R246K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); called by muse, mutect2
- DPP6 | c.2307G>A p.M769I (on ENST00000377770 / NM_001364500.2; = p.M707I on NM_001936.5) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2
- DUOX2 | c.1264_1291del p.R422Nfs*52 | Frame Shift Del (DEL) | VAF 11/82 reads (13%) | called by mutect2, pindel
- PRAMEF19 | c.374C>T p.S125F | Missense Mutation (SNP) | VAF 80/1230 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.12); called by muse, mutect2
- SMYD4 | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 15/165 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TCAF2 | c.2505+6G>C | Splice Region (SNP) | VAF 6/42 reads (14%) | called by mutect2, varscan2
- TEX2 | c.2574C>G p.L858= (on ENST00000583097 / NM_001288733.2; = p.L865= on NM_018469.5) | Splice Region (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2
- TPR | c.6955C>T p.Q2319* | Nonsense Mutation (SNP) | VAF 7/72 reads (10%) | called by muse, mutect2
- VPS26C | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 4/92 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- ZNF257 | c.1238C>G p.S413* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2, varscan2
- AAR2 | c.231C>T p.F77= | Silent (SNP) | VAF 6/112 reads (5%) | catalogued as COSV57924620; called by muse, mutect2
- ANO9 | c.936C>T p.L312= | Silent (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- CELF1 | c.1440G>A p.K480= (on ENST00000358597 / NM_001376422.1; = p.K476= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 18/324 reads (6%) | catalogued as COSV60114304; called by muse, mutect2
- CLCN1 | c.456G>A p.Q152= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV100578426, COSV58372920; called by muse, mutect2, varscan2
- COL6A6 | c.3495G>A p.K1165= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as COSV62018504, COSV62032984; called by muse, mutect2, varscan2
- DENND5B | c.1563C>T p.V521= | Silent (SNP) | VAF 12/118 reads (10%) | catalogued as COSV60906231; called by muse, mutect2
- ERCC6 | c.1647G>C p.L549= | Silent (SNP) | VAF 14/138 reads (10%) | catalogued as COSV63393136; called by muse, mutect2, varscan2
- FER1L6 | c.4956C>T p.N1652= | Silent (SNP) | VAF 10/93 reads (11%) | catalogued as COSV67548932, COSV67551935; called by muse, mutect2, varscan2
- FSD1 | c.51G>A p.V17= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as COSV55698149; called by muse, mutect2, varscan2
- FXR1 | c.894A>G p.G298= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as COSV59765067; called by muse, mutect2, varscan2
- H4C4 | c.311G>A p.*104= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as COSV61591371, COSV61591431; called by muse, mutect2
- HTR2B | c.519C>T p.F173= | Silent (SNP) | VAF 14/266 reads (5%) | catalogued as COSV51450417; called by muse, mutect2
- IL15RA | c.744G>A p.P248= | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as rs778675420, COSV66093056; called by muse, mutect2, varscan2
- MIEF2 | c.894G>A p.E298= | Silent (SNP) | VAF 7/105 reads (7%) | catalogued as COSV59902353; called by muse, mutect2
- NCKAP1L | c.327C>G p.L109= | Silent (SNP) | VAF 48/226 reads (21%) | catalogued as COSV53210481; called by muse, mutect2, varscan2
- NIPSNAP1 | c.132C>T p.F44= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs1259553899, COSV53343546; called by muse, mutect2
- OR5D18 | c.573T>A p.S191= | Silent (SNP) | VAF 17/156 reads (11%) | catalogued as rs757493772, COSV61738162; called by muse, mutect2, varscan2
- OR5M1 | c.636C>T p.F212= | Silent (SNP) | VAF 16/119 reads (13%) | catalogued as COSV73202325; called by muse, mutect2, varscan2
- OR9G1 | c.690C>T p.S230= | Silent (SNP) | VAF 12/361 reads (3%) | catalogued as COSV56453051; called by muse, mutect2
- PARP6 | c.654G>A p.K218= | Silent (SNP) | VAF 72/542 reads (13%) | catalogued as rs28625945, COSV53004405; called by muse, mutect2, varscan2
- PARP9 | c.1555C>T p.L519= | Silent (SNP) | VAF 9/176 reads (5%) | catalogued as COSV64451469; called by muse, mutect2
- PLD1 | c.1818C>T p.L606= | Silent (SNP) | VAF 20/228 reads (9%) | catalogued as COSV60572130; called by muse, mutect2
- PSMB8 | c.198G>A p.Q66= (on ENST00000374882 / NM_148919.4; = p.Q62= on NM_004159.5) | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as COSV62755345; called by muse, mutect2
- RABGEF1 | c.342G>A p.V114= (on ENST00000439720 / NM_001287061.2; = p.V101= on NM_014504.3 and 29 other RefSeq transcripts) | Silent (SNP) | VAF 6/77 reads (8%) | catalogued as COSV53164028; called by muse, mutect2
- RAD23A | c.9C>T p.V3= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as rs1195827062, COSV57117230; called by muse, mutect2, varscan2
- RIN3 | c.2325C>G p.L775= | Silent (SNP) | VAF 10/95 reads (11%) | catalogued as COSV53653411; called by muse, mutect2, varscan2
- RTL6 | c.543C>G p.L181= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV57979441, COSV57980049; called by muse, mutect2, varscan2
- SCN5A | c.5994T>C p.S1998= (on ENST00000333535 / NM_198056.3; = p.S1997= on NM_000335.5) | Silent (SNP) | VAF 17/115 reads (15%) | catalogued as rs1057520490, COSV61135118; ClinVar: likely benign; called by muse, mutect2, varscan2
- SKOR1 | c.345G>A p.E115= | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as COSV58248857; called by muse, mutect2, varscan2
- SLC5A1 | c.1834C>T p.L612= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as rs1377222551, COSV56687914; called by muse, mutect2, varscan2
- SUPT16H | c.45G>A p.K15= | Silent (SNP) | VAF 10/93 reads (11%) | catalogued as COSV53526768; called by muse, mutect2
- SUPT6H | c.3276C>T p.I1092= | Silent (SNP) | VAF 5/82 reads (6%) | catalogued as COSV58929091; called by muse, mutect2
- TAS2R31 | c.306C>A p.L102= | Silent (SNP) | VAF 10/246 reads (4%) | catalogued as COSV66831025; called by muse, mutect2
- TBC1D9B | c.3534C>T p.G1178= (on ENST00000356834 / NM_198868.3; = p.G1161= on NM_015043.4) | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as rs199501173, COSV52972733; called by muse, mutect2, varscan2
- TCTN1 | c.718C>T p.L240= | Silent (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- TMPPE | c.777C>T p.V259= | Silent (SNP) | VAF 28/119 reads (24%) | catalogued as rs367832132; called by muse, mutect2, varscan2
- USP21 | c.900G>A p.Q300= | Silent (SNP) | VAF 9/91 reads (10%) | catalogued as rs1361631774, COSV57090400, COSV99237351; called by muse, mutect2, varscan2
- VCP | c.1023G>A p.V341= | Silent (SNP) | VAF 14/100 reads (14%) | catalogued as COSV62721670; called by muse, mutect2, varscan2
- ZNF280A | c.900C>T p.C300= | Silent (SNP) | VAF 35/222 reads (16%) | catalogued as COSV57481684; called by muse, mutect2, varscan2
- ZNF615 | c.1146C>G p.T382= | Silent (SNP) | VAF 10/105 reads (10%) | catalogued as COSV65032178, COSV65034522; called by muse, mutect2
- ZZEF1 | c.3639G>A p.L1213= | Silent (SNP) | VAF 14/220 reads (6%) | catalogued as COSV67559310; called by muse, mutect2
- KRT71 | c.*2G>A | 3'UTR (SNP) | VAF 31/316 reads (10%) | catalogued as rs780465122, COSV99922325; called by muse, mutect2
- OR2AK2 | c.-5C>T | 5'UTR (SNP) | VAF 7/120 reads (6%) | catalogued as COSV100824223; called by muse, mutect2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 5/29 reads (17%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
